Somatic mutation profile of tumor specimen ALCH-B4K6-TTP1-A (aliquot ALCH-B4K6-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4K6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.7 years (19,990 days).
Specimen ALCH-B4K6-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a397746b-43a9-4d92-b453-6e83cc327f70.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4K6-NB1-A (Blood Derived Normal), aliquot ALCH-B4K6-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7dcccbc-cd2b-4e87-8237-caa8379fa3be

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, Nonsense Mutation 3, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BIRC6 | c.12286C>T p.Q4096* | Nonsense Mutation (SNP) | VAF 29/87 reads (33%) | catalogued as COSV66042885; called by muse, mutect2, varscan2
- CSMD3 | c.8040G>A p.W2680* (on ENST00000297405 / NM_001363185.1; = p.W2576* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 98/333 reads (29%) | catalogued as COSV52170124; called by muse, mutect2, varscan2
- MORC1 | c.2098G>C p.E700Q | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV51718133; called by muse, mutect2, varscan2
- PRDM8 | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 73/257 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as rs199585477; called by muse, mutect2, varscan2
- RYR3 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs548943211, COSV66811721; called by muse, mutect2, varscan2
- B4GALNT4 | c.650G>A p.W217* | Nonsense Mutation (SNP) | VAF 25/112 reads (22%) | called by muse, mutect2, varscan2
- CCDC9 | c.1340C>A p.A447D | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- CHD9 | c.3229A>G p.M1077V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CLEC2B | c.43T>G p.L15V | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNGB1 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 99/442 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- FAM47C | c.2813A>G p.Y938C | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MED13 | c.6422C>A p.S2141Y | Missense Mutation (SNP) | VAF 108/361 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MORC1 | c.2099A>T p.E700V | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- POLG2 | c.80C>A p.A27E | Missense Mutation (SNP) | VAF 113/336 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RBM12 | c.1087A>T p.N363Y | Missense Mutation (SNP) | VAF 93/261 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RPL11 | c.240_260del p.I81_K87del (on ENST00000374550 / NM_001199802.1; = p.I82_K88del on NM_000975.5) | In Frame Del (DEL) | VAF 48/229 reads (21%) | called by mutect2, pindel
- ACAP3 | c.996C>T p.F332= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as rs748095891; called by muse, mutect2, varscan2
- DYRK1B | c.945C>G p.G315= | Silent (SNP) | VAF 26/81 reads (32%) | called by muse, mutect2, varscan2
- MESP2 | c.213C>T p.P71= | Silent (SNP) | VAF 9/173 reads (5%) | called by muse, mutect2
- TAB2 | c.1953C>T p.I651= | Silent (SNP) | VAF 130/259 reads (50%) | called by muse, mutect2, varscan2
- ZYG11A | c.2088T>C p.H696= | Silent (SNP) | VAF 56/177 reads (32%) | called by muse, mutect2, varscan2
- MRNIP | c.126+34C>T | Intron (SNP) | VAF 96/379 reads (25%) | called by muse, mutect2, varscan2
